Somatic mutation profile of tumor specimen TCGA-B5-A11H-01A (aliquot TCGA-B5-A11H-01A-11D-A122-09) from TCGA case TCGA-B5-A11H, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.2 years (24,556 days).
Specimen TCGA-B5-A11H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76a53025-e904-4a46-a8f9-175ecf74b687.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11H-10B (Blood Derived Normal), aliquot TCGA-B5-A11H-10B-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41c73313-f4ae-4a83-83f8-977d57804506

The open-access MAF lists 1,233 somatic variants for this specimen: 962 protein-altering or splice-affecting, 248 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 593, Silent 248, Frame Shift Del 240, Frame Shift Ins 48, Nonsense Mutation 33, In Frame Del 21, Splice Site 16, 3'UTR 7, Intron 7, Splice Region 6, Translation Start Site 4, 5'Flank 4.

Variants (750 of 1,233; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131691916, CM000638, COSV54384619; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BCL10 | c.499del p.S167Lfs*6 | Frame Shift Del (DEL) | VAF 66/253 reads (26%) | catalogued as rs387906350, COSV65354275; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 112/348 reads (32%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- CHD7 | c.8962dup p.D2988Gfs*2 | Frame Shift Ins (INS) | VAF 17/57 reads (30%) | catalogued as rs771806027, CI084262; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CWC27 | c.1002del p.V335* | Frame Shift Del (DEL) | VAF 136/412 reads (33%) | catalogued as rs752159903; ClinVar: pathogenic; called by mutect2, varscan2
- CYP27B1 | c.171dup p.L58Afs*275 | Frame Shift Ins (INS) | VAF 22/79 reads (28%) | catalogued as rs763437121; ClinVar: pathogenic; called by mutect2, varscan2
- HNF1B | c.1561del p.Q521Sfs*70 | Frame Shift Del (DEL) | VAF 86/324 reads (27%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ITK | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs397514261, CM121080, COSV101439808, COSV70061950, COSV70062223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 112/358 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750206, CM093753, CM970953, CM990854, COSV51614574, COSV51617724; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6016G>A p.V2006I | Missense Mutation (SNP) | VAF 73/264 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV63868121, COSV63871144, COSV63874589; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 26/78 reads (33%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NPHS2 | c.467del p.L156Cfs*25 | Frame Shift Del (DEL) | VAF 43/113 reads (38%) | catalogued as rs528833893, CD042219; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PHGDH | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs587777483, CM145878, COSV65570892; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 39/124 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1553821144, COSV55877939, COSV55937337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 127/427 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.607_608del p.I203Sfs*39 | Frame Shift Del (DEL) | VAF 55/284 reads (19%) | catalogued as rs1085308054; ClinVar: pathogenic; called by pindel, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 92/296 reads (31%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- TECTA | c.6062G>A p.R2021H | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs121909062, CM023689, COSV50718488; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.12107del p.P4036Qfs*14 (on ENST00000591111; = p.P3990Qfs*14 on NM_003319.4) | Frame Shift Del (DEL) | VAF 56/186 reads (30%) | catalogued as rs1408345511; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- UGDH | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.812); catalogued as rs1053767552, COSV57097676; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ZFYVE26 | c.5321-2A>G p.X1774_splice | Splice Site (SNP) | VAF 52/161 reads (32%) | catalogued as rs1555395560, COSV61328137; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs762797321, COSV57923909; called by muse, mutect2, varscan2
- AASS | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 148/460 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV62789931; called by muse, mutect2, varscan2
- ABCA7 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV54029096; called by muse, mutect2
- ABCB1 | c.2920G>T p.V974F | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55950668; called by muse, mutect2, varscan2
- ABCB10 | c.1389del p.R464Afs*20 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | catalogued as rs1406695210; called by mutect2, pindel, varscan2
- ABCB8 | c.459G>T p.V153= (on ENST00000297504 / NM_001282291.2; = p.V136= on NM_007188.5) | Splice Region (SNP) | VAF 15/44 reads (34%) | catalogued as rs767172962, COSV52504405; called by muse, mutect2, varscan2
- ABCC3 | c.1651C>A p.L551I | Missense Mutation (SNP) | VAF 109/335 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV53321363; called by muse, mutect2, varscan2
- ABCD1 | c.350G>T p.R117M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV54384610; called by muse, mutect2, varscan2
- ABR | c.2059G>A p.V687M (on ENST00000302538 / NM_021962.5; = p.V650M on NM_001092.5) | Missense Mutation (SNP) | VAF 105/294 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs200785190, COSV52145434; called by muse, mutect2, varscan2
- AC242842.3 | c.238_240del p.E80del | In Frame Del (DEL) | VAF 53/349 reads (15%) | catalogued as rs1393554724; called by pindel, varscan2
- ACACB | c.6445T>A p.L2149M | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58134082; called by muse, mutect2, varscan2
- ACAD11 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 65/190 reads (34%) | catalogued as COSV53896039; called by muse, mutect2, varscan2
- ACE2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV53024913; called by muse, mutect2, varscan2
- ACO1 | c.670A>G p.I224V | Missense Mutation (SNP) | VAF 127/242 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59379759; called by muse, mutect2, varscan2
- ACO1 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59379776, COSV59380867; called by muse, mutect2, varscan2
- ACSM2B | c.1529T>C p.I510T | Missense Mutation (SNP) | VAF 111/390 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs1197904437, COSV61657792; called by muse, mutect2, varscan2
- ACSS2 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs753153922, COSV53624557; called by muse, mutect2, varscan2
- ACTL8 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs373308699; called by muse, mutect2, varscan2
- ACTN4 | c.2619del p.D874Tfs*44 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as rs869292397; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 76/258 reads (29%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 50/164 reads (30%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS4 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146858388; called by muse, mutect2, varscan2
- ADAMTS6 | c.630G>C p.S210= | Splice Region (SNP) | VAF 137/418 reads (33%) | catalogued as COSV66859520; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs587619905, COSV55004061, COSV99647551; ClinVar: uncertain significance; called by muse, mutect2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 42/83 reads (51%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA3 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 7/204 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99293741; called by muse, mutect2
- ADGRG4 | c.1217C>A p.T406N | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs774049812, COSV54955463; called by muse, mutect2, varscan2
- AHDC1 | c.4154A>G p.H1385R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.381); catalogued as COSV55938757; called by muse, mutect2, varscan2
- AIFM1 | c.1771-2A>G p.X591_splice | Splice Site (SNP) | VAF 146/505 reads (29%) | catalogued as COSV54854479; called by muse, mutect2, varscan2
- AJUBA | c.93del p.P33Rfs*6 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as COSV99401168; called by mutect2, pindel, varscan2
- AKAP6 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV55213266; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 42/152 reads (28%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ALG11 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV73000652; called by muse, mutect2, varscan2
- ALG6 | c.663dup p.G222Rfs*12 | Frame Shift Ins (INS) | VAF 82/322 reads (25%) | catalogued as rs964851138; called by mutect2, pindel, varscan2
- ALMS1 | c.1700C>T p.T567I | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs752312999, COSV52509412; called by muse, mutect2, varscan2
- ALOX15 | c.952-2A>G p.X318_splice | Splice Site (SNP) | VAF 36/214 reads (17%) | catalogued as COSV53397637; called by muse, mutect2, varscan2
- AMBRA1 | c.3851G>A p.S1284N (on ENST00000458649 / NM_001367468.1; = p.S1194N on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54053426; called by muse, mutect2, varscan2
- AMER2 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.098); catalogued as COSV63437373; called by muse, mutect2, varscan2
- AMZ2 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 197/626 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV63082940; called by muse, mutect2, varscan2
- ANKRD27 | c.2891C>A p.P964H | Missense Mutation (SNP) | VAF 88/310 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV60131429; called by mutect2, varscan2
- ANKRD30A | c.1228G>A p.A410T (on ENST00000611781; = p.A354T on NM_052997.2) | Missense Mutation (SNP) | VAF 95/296 reads (32%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.956); catalogued as rs760965708, COSV64608046; called by muse, mutect2, varscan2
- ANKRD50 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs371516395; called by muse, mutect2, varscan2
- APOB | c.3501G>A p.W1167* | Nonsense Mutation (SNP) | VAF 69/269 reads (26%) | catalogued as COSV51934573; called by muse, mutect2, varscan2
- APOF | c.57_59del p.M19del | In Frame Del (DEL) | VAF 51/156 reads (33%) | catalogued as rs924804781; called by mutect2, pindel, varscan2
- APOOL | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 106/384 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.239); catalogued as COSV64271625; called by muse, mutect2, varscan2
- AQP12A | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs143658178; called by muse, mutect2, varscan2
- ARFGEF2 | c.4139G>A p.R1380Q | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs202242624, COSV64212155, COSV64212436; called by mutect2, varscan2
- ARG1 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.238); catalogued as COSV51580989; called by muse, mutect2, varscan2
- ARHGAP31 | c.432-1G>A p.X144_splice | Splice Site (SNP) | VAF 42/127 reads (33%) | catalogued as COSV51792671, COSV51796654; called by muse, mutect2, varscan2
- ARHGAP31 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as rs1205008776, COSV51792683; called by muse, varscan2
- ARHGAP31 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.088); catalogued as COSV51792693, COSV51795432; called by muse, varscan2
- ARID1B | c.3374C>T p.A1125V | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV51660788; called by muse, mutect2, varscan2
- ARID5A | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as rs544764108, COSV62591108, COSV62591518; called by muse, mutect2, varscan2
- ARMC4 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.679); catalogued as rs142598573; called by muse, mutect2, varscan2
- ARVCF | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs141228868; called by muse, mutect2, varscan2
- ASTN2 | c.2927G>A p.R976H (on ENST00000313400 / NM_001365069.1; = p.R925H on NM_014010.5) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs148503875; called by muse, mutect2, varscan2
- ASXL2 | c.3859G>A p.E1287K | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs756290348, COSV55458420; called by muse, mutect2, varscan2
- ASXL3 | c.6110del p.P2037Hfs*43 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs747712363; called by mutect2, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATF6 | c.1820G>T p.G607V | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV63407372; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 60/267 reads (22%) | catalogued as rs771531141; called by mutect2, varscan2
- ATN1 | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.061); catalogued as rs148828880; called by muse, mutect2, varscan2
- ATOH1 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs761788317, COSV60037901; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 110/362 reads (30%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP12A | c.2573G>T p.R858M | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54515822; called by muse, varscan2
- ATP13A1 | c.1787C>T p.T596M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.277); catalogued as rs973955925, COSV52284834; called by muse, mutect2, varscan2
- ATP2B1 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV53805064, COSV53807289; called by muse, mutect2, varscan2
- ATP9B | c.3184G>A p.V1062I | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147969611; called by muse, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 57/184 reads (31%) | catalogued as COSV59620972; called by mutect2, varscan2
- BAG1 | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV56302949; called by muse, varscan2
- BAP1 | c.631A>G p.M211V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV56234124; called by muse, mutect2, varscan2
- BCL7C | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); catalogued as rs917615271, COSV53063424; called by muse, mutect2, varscan2
- BCL9 | c.2575G>T p.G859C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV52344002; called by muse, mutect2, varscan2
- BCOR | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.11); catalogued as COSV60706633; called by muse, mutect2, varscan2
- BDP1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs750016343, COSV62430268; called by muse, mutect2, varscan2
- BPI | c.752T>A p.L251Q (on ENST00000262865; = p.L247Q on NM_001725.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53405552; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 78/226 reads (35%) | catalogued as COSV56263190; called by mutect2, varscan2
- BRD1 | c.1468del p.A490Pfs*26 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as COSV53458006; called by mutect2, pindel, varscan2
- BRD4 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as COSV54586073; called by muse, mutect2, varscan2
- BTBD7 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV58285798; called by muse, mutect2, varscan2
- BTN1A1 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.141); catalogued as COSV55067573; called by muse, mutect2, varscan2
- C11orf42 | c.97A>G p.N33D | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.055); catalogued as COSV56411249; called by muse, mutect2, varscan2
- C11orf68 | c.730C>T p.R244C (on ENST00000530188; = p.R285C on NM_031450.4) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs1001663632; called by muse, mutect2, varscan2
- C12orf4 | c.707del p.N236Tfs*22 | Frame Shift Del (DEL) | VAF 236/896 reads (26%) | catalogued as COSV54210606; called by mutect2, pindel, varscan2
- C1QL2 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753210008, COSV55606549; called by muse, mutect2, varscan2
- C1orf127 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.855); catalogued as rs779082540, COSV65437201; called by muse, mutect2, varscan2
- C3orf33 | c.633del p.G212Efs*15 (on ENST00000340171 / NM_001308229.2; = p.G169Efs*15 on NM_173657.2) | Frame Shift Del (DEL) | VAF 90/260 reads (35%) | catalogued as rs762988845; called by mutect2, varscan2
- C7 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 100/298 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100495299, COSV57474043; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 243/631 reads (39%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CAAP1 | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV61700397; called by muse, mutect2, varscan2
- CACFD1 | c.218T>C p.L73P | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52469873; called by muse, mutect2, varscan2
- CACNA1F | c.5795C>T p.T1932M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs782460359, COSV59903235; called by muse, mutect2, varscan2
- CACNA1F | c.1891A>G p.R631G | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59904372; called by muse, mutect2, varscan2
- CACNB1 | c.905T>A p.V302E | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59998775; called by muse, mutect2, varscan2
- CACNB2 | c.1124C>T p.A375V (on ENST00000324631 / NM_201596.3; = p.A320V on NM_000724.4) | Missense Mutation (SNP) | VAF 104/340 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs578106427, COSV56622691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMK2A | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV62245362, COSV62246303; called by muse, mutect2, varscan2
- CAMK2B | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 95/394 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51660274; called by muse, mutect2, varscan2
- CAMK2G | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 145/449 reads (32%) | catalogued as COSV59481800; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 48/186 reads (26%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA1 | c.4767del p.K1589Nfs*33 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as rs754008719; called by mutect2, varscan2
- CAMTA2 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761354207, COSV61834763; called by muse, mutect2, varscan2
- CAPN5 | c.305G>A p.R102H (on ENST00000456580; = p.R62H on NM_004055.5) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as rs199504989, COSV53687681; called by muse, mutect2, varscan2
- CARD11 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1211022340, COSV62755200; called by muse, mutect2, varscan2
- CARS1 | c.377T>C p.L126S | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV53454026; called by muse, mutect2, varscan2
- CASQ2 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 144/456 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756155045, COSV54770268; called by muse, mutect2, varscan2
- CBX8 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.68); catalogued as rs142520694; called by muse, mutect2, varscan2
- CC2D1A | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs560714416, COSV58783143; called by muse, mutect2, varscan2
- CC2D2A | c.2528C>A p.S843* | Nonsense Mutation (SNP) | VAF 70/264 reads (27%) | catalogued as COSV67503568; called by muse, mutect2, varscan2
- CCDC50 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776014358, COSV66667353; called by muse, mutect2
- CCNE1 | c.191A>T p.N64I | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV52904350; called by muse, mutect2, varscan2
- CCPG1 | c.2257C>T p.H753Y | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51241692; called by muse, mutect2, varscan2
- CD101 | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56717921; called by muse, mutect2, varscan2
- CDC25A | c.1336A>T p.R446* | Nonsense Mutation (SNP) | VAF 71/244 reads (29%) | catalogued as COSV56769745; called by muse, mutect2, varscan2
- CDC42BPB | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1287907520, COSV63474845; called by muse, mutect2, varscan2
- CDCA4 | c.23G>T p.R8M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60315345; called by muse, mutect2, varscan2
- CDH19 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 120/381 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050775, COSV50958471; called by muse, mutect2, varscan2
- CDH8 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 106/354 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866984859, COSV54865725; called by muse, varscan2
- CDH8 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0.012); catalogued as COSV54865736; called by muse, mutect2, varscan2
- CDHR1 | c.1882del p.E628Rfs*27 | Frame Shift Del (DEL) | VAF 43/143 reads (30%) | catalogued as COSV60560186; called by mutect2, pindel, varscan2
- CDK18 | c.536A>G p.K179R (on ENST00000506784 / NM_212503.3; = p.K149R on NM_002596.4) | Missense Mutation (SNP) | VAF 139/469 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1472516669, COSV63727412; called by muse, mutect2, varscan2
- CDON | c.1885C>T p.H629Y | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.41); catalogued as rs1208368356, COSV54996899; called by muse, mutect2, varscan2
- CEACAM19 | c.212C>G p.T71R | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV62551977; called by muse, mutect2, varscan2
- CELF3 | c.676C>A p.L226I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.984); catalogued as COSV51883324; called by muse, varscan2
- CELSR1 | c.5544del p.T1849Rfs*8 | Frame Shift Del (DEL) | VAF 34/133 reads (26%) | catalogued as rs776824429; called by mutect2, pindel, varscan2
- CEMIP2 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as COSV65487135; called by muse, mutect2, varscan2
- CEP350 | c.6232del p.R2078Gfs*6 | Frame Shift Del (DEL) | VAF 96/360 reads (27%) | catalogued as rs759430139; called by pindel, varscan2
- CEP43 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as rs528148538, COSV62760809; called by muse, mutect2, varscan2
- CES2 | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs1047896399, COSV57696817; called by muse, mutect2, varscan2
- CETN3 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 158/508 reads (31%) | catalogued as rs1328760562, COSV51617259; called by mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 56/261 reads (21%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CFAP91 | c.1367A>G p.K456R | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); catalogued as COSV56340848; called by muse, mutect2, varscan2
- CFHR3 | c.415A>G p.R139G | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.867); catalogued as COSV66402114; called by muse, mutect2, varscan2
- CHD7 | c.8532G>T p.E2844D | Missense Mutation (SNP) | VAF 91/350 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV71110088; called by muse, mutect2, varscan2
- CHERP | c.1136G>A p.S379N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV52223492; called by muse, mutect2, varscan2
- CHRM1 | c.935A>G p.Q312R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as COSV61006646; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as rs751548647; called by mutect2, varscan2
- CLASP1 | c.3692dup p.S1232* | Frame Shift Ins (INS) | VAF 28/129 reads (22%) | catalogued as rs749719822; called by mutect2, varscan2
- CLCA4 | c.2209G>T p.G737C | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65283388; called by muse, mutect2, varscan2
- CLCN2 | c.1142del p.P381Lfs*35 | Frame Shift Del (DEL) | VAF 50/204 reads (25%) | catalogued as rs1217596296; called by mutect2, pindel, varscan2
- CLINT1 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV51623850; called by muse, mutect2, varscan2
- CMTR1 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as rs1330893752, COSV100990896, COSV65090307; called by muse, mutect2, varscan2
- CNP | c.52_54del p.F18del | In Frame Del (DEL) | VAF 56/162 reads (35%) | catalogued as rs782370320; called by pindel, varscan2
- CNTN2 | c.2630G>A p.G877D | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs748124415, COSV59349930; called by muse, mutect2, varscan2
- CNTNAP2 | c.3433C>T p.L1145F | Missense Mutation (SNP) | VAF 186/566 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1284175785, COSV62177652; called by muse, mutect2, varscan2
- CNTRL | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 79/154 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs369768072, COSV53046774; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as rs374805044; called by mutect2, varscan2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 66/202 reads (33%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COIL | c.192del p.L65Sfs*11 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs763239843; called by mutect2, varscan2
- COL23A1 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 108/316 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs771283008, COSV66790305; called by muse, mutect2, varscan2
- COL2A1 | c.3415C>T p.Q1139* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV61530325; called by muse, mutect2, varscan2
- COL4A2 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs570979461, COSV64628032, COSV64631488; called by muse, mutect2, varscan2
- COL4A6 | c.4667T>C p.V1556A | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV57865962; called by muse, mutect2, varscan2
- COL8A1 | c.1472A>G p.Q491R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53734131; called by muse, mutect2, varscan2
- COL9A1 | c.1187del p.P396Qfs*33 | Frame Shift Del (DEL) | VAF 46/152 reads (30%) | catalogued as rs983596283; called by mutect2, varscan2
- COLGALT1 | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53108832; called by muse, mutect2, varscan2
- COMP | c.1933G>T p.G645C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55874727; called by muse, mutect2, varscan2
- CPA3 | c.187A>G p.N63D | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs1454852497, COSV56045061; called by muse, mutect2, varscan2
- CPEB1 | c.1116G>T p.K372N (on ENST00000617958; = p.K312N on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/285 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55618885; called by muse, mutect2, varscan2
- CPLANE1 | c.8035C>T p.R2679W | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs142792453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPM | c.200A>G p.K67R | Missense Mutation (SNP) | VAF 119/380 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV58033149; called by muse, mutect2, varscan2
- CPN2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.209); catalogued as COSV60470331; called by muse, mutect2, varscan2
- CR1 | c.4213G>A p.A1405T | Missense Mutation (SNP) | VAF 148/519 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as COSV65458112; called by muse, mutect2, varscan2
- CRACD | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs763506093, COSV51720531; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs747248693; called by mutect2, varscan2
- CSMD1 | c.5113C>T p.P1705S (on ENST00000520002; = p.P1704S on NM_033225.6) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs930463893, COSV59320572; called by muse, mutect2, varscan2
- CSMD3 | c.10901C>T p.A3634V (on ENST00000297405 / NM_001363185.1; = p.A3465V on NM_052900.3) | Missense Mutation (SNP) | VAF 17/397 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52172348; called by muse, mutect2
- CSRNP1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs112383054, COSV56187931; called by muse, mutect2, varscan2
- CTC1 | c.77C>A p.T26N | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV59853237; called by muse, mutect2, varscan2
- CTNNA3 | c.1145T>C p.I382T | Missense Mutation (SNP) | VAF 95/314 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV65579467; called by muse, mutect2, varscan2
- CUL7 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as rs751379076, COSV54816609; called by muse, mutect2, varscan2
- CX3CR1 | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV64193796; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP11B1 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.154); catalogued as rs1478938813, COSV52826941; called by muse, mutect2, varscan2
- CYP26B1 | c.574A>G p.M192V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV50011745; called by muse, mutect2, varscan2
- CYP7A1 | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.877); catalogued as COSV56963395; called by muse, mutect2, varscan2
- DACH2 | c.1187G>A p.S396N | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as rs968435059, COSV64168244; called by muse, mutect2, varscan2
- DAPK1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.502); catalogued as rs777469310, COSV63787212; called by muse, mutect2, varscan2
- DBF4B | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs761312763, COSV59260434; called by muse, mutect2, varscan2
- DCAF12 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775160589, COSV63512447; called by muse, mutect2, varscan2
- DDX41 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.26); catalogued as COSV57903322; called by muse, mutect2, varscan2
- DDX58 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 112/258 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs772999380, COSV65883087; called by muse, varscan2
- DDX60 | c.4186T>C p.S1396P | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as COSV67096651; called by muse, mutect2, varscan2
- DENND4C | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs780075622, COSV66822089; called by muse, mutect2, varscan2
- DHTKD1 | c.1858del p.L620* | Frame Shift Del (DEL) | VAF 65/406 reads (16%) | catalogued as COSV53802665; called by mutect2, pindel, varscan2
- DHX40 | c.1877G>A p.G626D | Missense Mutation (SNP) | VAF 93/326 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52067397; called by muse, mutect2, varscan2
- DLGAP2 | c.2447G>T p.S816I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as COSV70097871; called by muse, mutect2, varscan2
- DLL1 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 87/312 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs766516902, COSV64536592; called by muse, mutect2, varscan2
- DLL4 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51062424; called by muse, mutect2, varscan2
- DLX2 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV99308659; called by muse, mutect2
- DNAH1 | c.5480G>A p.R1827H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs377201322; called by muse, mutect2, varscan2
- DNAH10 | c.3122A>G p.H1041R (on ENST00000409039; = p.H980R on NM_207437.3) | Missense Mutation (SNP) | VAF 90/285 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV68993343; called by muse, mutect2, varscan2
- DNAH5 | c.8827C>T p.R2943C | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758324905, COSV54218613; called by muse, mutect2, varscan2
- DNAH7 | c.7178A>G p.Q2393R | Missense Mutation (SNP) | VAF 69/259 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.281); catalogued as COSV56763803; called by muse, mutect2, varscan2
- DNAH8 | c.1339A>G p.S447G | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as COSV59443776; called by muse, mutect2, varscan2
- DNAI4 | c.1597T>C p.Y533H | Missense Mutation (SNP) | VAF 69/235 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV64021750; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 53/194 reads (27%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK6 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.309); catalogued as COSV53914419; called by muse, mutect2, varscan2
- DRC3 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs201927277, COSV58263224; called by muse, mutect2, varscan2
- DTNB | c.1739C>T p.T580M | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs373391383; called by muse, mutect2, varscan2
- DUOX2 | c.4432C>T p.R1478W | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs371970228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1H1 | c.291A>C p.E97D | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV64136743; called by muse, mutect2, varscan2
- DYNC1H1 | c.5948G>A p.R1983H | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs200934709, COSV64136751; called by muse, mutect2, varscan2
- DYNC1I2 | c.105del p.E36Kfs*34 | Frame Shift Del (DEL) | VAF 53/164 reads (32%) | catalogued as rs755197346; called by mutect2, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 107/398 reads (27%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- DYSF | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV50316876; called by muse, mutect2, varscan2
- DZIP1 | c.2522_2524del p.E841del (on ENST00000347108; = p.E822del on NM_014934.5) | In Frame Del (DEL) | VAF 75/284 reads (26%) | catalogued as rs762091765; called by mutect2, pindel, varscan2
- E2F5 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 152/339 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV56274711; called by muse, mutect2, varscan2
- ECRG4 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1408626614, COSV53000816; called by muse, mutect2, varscan2
- ECSIT | c.935del p.P312Rfs*26 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as COSV52938832; called by mutect2, pindel, varscan2
- EDN3 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1050787473, COSV61107924; called by muse, mutect2, varscan2
- EGR1 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV53519219; called by muse, mutect2, varscan2
- EIF2AK4 | c.4426C>T p.R1476C | Missense Mutation (SNP) | VAF 107/341 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1161134551, COSV55467484; called by muse, mutect2, varscan2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 20/86 reads (23%) | catalogued as rs769175197; called by mutect2, varscan2
- EMC1 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV64345754; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 86/362 reads (24%) | catalogued as rs770453803; called by mutect2, varscan2
- ENPP4 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 93/252 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV58088895; called by muse, mutect2, varscan2
- EP400 | c.3374G>A p.R1125H | Missense Mutation (SNP) | VAF 120/416 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs760368735, COSV57771561; called by muse, varscan2
- EPHB4 | c.2750G>A p.R917Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as rs778891426, COSV62268772, COSV62269956; called by muse, mutect2, varscan2
- EPHB6 | c.165+1dup | Frame Shift Ins (INS) | VAF 26/92 reads (28%) | catalogued as rs771807343; called by mutect2, varscan2
- ERBIN | c.1324A>G p.N442D | Missense Mutation (SNP) | VAF 101/289 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as COSV52315852; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 158/673 reads (23%) | catalogued as rs753821453; called by mutect2, varscan2
- ESPNL | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV58034473; called by muse, mutect2, varscan2
- ESRP2 | c.1316C>T p.A439V (on ENST00000565858 / NM_001365264.1; = p.A429V on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV52173369; called by muse, mutect2, varscan2
- ETS1 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as rs766964257, COSV60092018; called by muse, mutect2, varscan2
- FAHD2A | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 73/270 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51977460, COSV51978124; called by muse, mutect2, varscan2
- FAM120C | c.2116A>C p.T706P | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as COSV60259235, COSV60260794; called by muse, mutect2, varscan2
- FAM135B | c.1566A>T p.Q522H | Missense Mutation (SNP) | VAF 129/258 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as COSV52723116; called by muse, mutect2, varscan2
- FAM161A | c.517T>C p.S173P | Missense Mutation (SNP) | VAF 118/371 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as rs761535974, COSV56765966; called by muse, mutect2, varscan2
- FAM171A1 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs769373116, COSV100968289, COSV65315866; called by muse, mutect2, varscan2
- FAT1 | c.10363G>A p.V3455M | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV71673729; called by muse, mutect2, varscan2
- FAT1 | c.9683del p.P3228Lfs*42 | Frame Shift Del (DEL) | VAF 24/112 reads (21%) | catalogued as rs1010116749; called by mutect2, pindel, varscan2
- FAT3 | c.7443G>T p.Q2481H | Missense Mutation (SNP) | VAF 85/263 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53107288; called by muse, mutect2, varscan2
- FBN3 | c.2259del p.G754Afs*23 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as COSV54456788; called by mutect2, pindel, varscan2
- FBRS | c.1126C>T p.R376C (on ENST00000287468; = p.R896C on NM_001105079.3) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs143154229; called by muse, mutect2, varscan2
- FBXO47 | c.1229A>G p.Q410R | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1254021375, COSV65241728; called by muse, mutect2, varscan2
- FCAMR | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.09); catalogued as COSV61367631; called by muse, mutect2, varscan2
- FEN1 | c.641A>C p.Q214P | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV57250801; called by muse, mutect2, varscan2
- FGGY | c.379A>G p.N127D | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58032678; called by muse, mutect2, varscan2
- FILIP1 | c.3157T>C p.Y1053H | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52729027; called by muse, mutect2, varscan2
- FLACC1 | c.310A>G p.M104V | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV53783730, COSV53786757; called by muse, mutect2, varscan2
- FLII | c.2840A>C p.E947A | Missense Mutation (SNP) | VAF 92/310 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV57497848; called by muse, mutect2, varscan2
- FOXN3 | c.668A>G p.Q223R | Missense Mutation (SNP) | VAF 156/630 reads (25%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.532); catalogued as COSV54308406; called by muse, mutect2, varscan2
- FRMD3 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs777625741, COSV58461057; called by muse, mutect2, varscan2
- FRMD4A | c.1715T>C p.L572P | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV62266000; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 79/253 reads (31%) | catalogued as rs756304971; called by mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 30/104 reads (29%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GAB2 | c.241C>T p.Q81* (on ENST00000361507 / NM_080491.3; = p.Q43* on NM_012296.3) | Nonsense Mutation (SNP) | VAF 108/307 reads (35%) | catalogued as COSV60867740; called by muse, mutect2, varscan2
- GABRE | c.1138-1G>A p.X380_splice | Splice Site (SNP) | VAF 25/95 reads (26%) | catalogued as COSV64818775, COSV64819581; called by muse, mutect2, varscan2
- GALNT10 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV51726207; called by muse, mutect2, varscan2
- GALNT5 | c.1970dup p.N657Kfs*4 | Frame Shift Ins (INS) | VAF 154/548 reads (28%) | catalogued as rs778901995; called by mutect2, pindel, varscan2
- GAMT | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140778208, CX129706; called by muse, varscan2
- GAS2L2 | c.1226del p.P409Lfs*92 | Frame Shift Del (DEL) | VAF 105/355 reads (30%) | catalogued as rs782212939; called by mutect2, pindel, varscan2
- GBA3 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 99/345 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs774310115, COSV72438096; called by muse, mutect2, varscan2
- GBF1 | c.2014_2015insT p.G672Vfs*3 (on ENST00000369983 / NM_001377137.1; = p.G671Vfs*3 on NM_004193.3) | Frame Shift Ins (INS) | VAF 33/160 reads (21%) | catalogued as COSV100890654; called by mutect2, pindel, varscan2
- GCC2 | c.2106dup p.Q703Tfs*4 | Frame Shift Ins (INS) | VAF 58/192 reads (30%) | catalogued as rs756364486; called by mutect2, varscan2
- GCC2 | c.3976C>T p.R1326* | Nonsense Mutation (SNP) | VAF 92/244 reads (38%) | catalogued as COSV59175366; called by muse, mutect2, varscan2
- GDA | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52992919; called by muse, mutect2, varscan2
- GDF11 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761420405, COSV57689309, COSV57689595; called by muse, mutect2, varscan2
- GEMIN5 | c.3299A>T p.N1100I | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53560464; called by muse, mutect2, varscan2
- GFPT1 | c.1106-1G>C p.X369_splice (on ENST00000357308 / NM_001244710.2; = p.X351_splice on NM_002056.4) | Splice Site (SNP) | VAF 64/205 reads (31%) | catalogued as COSV61947937; called by muse, mutect2, varscan2
- GIT1 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs903621709, COSV56402429; called by muse, mutect2, varscan2
- GJA9 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 120/381 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV62531917; called by muse, mutect2, varscan2
- GLP1R | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs201355669, COSV64714892; called by muse, mutect2, varscan2
- GLTPD2 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as COSV58702485; called by muse, mutect2, varscan2
- GLYR1 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.421); catalogued as COSV58927019; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 16/43 reads (37%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAL | c.1010del p.T337Rfs*69 (on ENST00000269162 / NM_001142339.3; = p.T414Rfs*69 on NM_182978.4) | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as COSV52327019; called by mutect2, pindel, varscan2
- GOLGA4 | c.1411A>T p.K471* | Nonsense Mutation (SNP) | VAF 115/356 reads (32%) | catalogued as COSV62710587; called by muse, mutect2, varscan2
- GORASP2 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 129/425 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52201853; called by muse, mutect2, varscan2
- GP2 | c.941T>C p.L314P (on ENST00000381362 / NM_001007240.3; = p.L311P on NM_001502.4) | Missense Mutation (SNP) | VAF 312/957 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56893910; called by muse, mutect2, varscan2
- GPAT3 | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV52356864; called by muse, mutect2, varscan2
- GPBP1L1 | c.1376A>G p.D459G | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.993); catalogued as COSV51969202; called by muse, mutect2, varscan2
- GPIHBP1 | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 159/293 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV58209191; called by muse, mutect2, varscan2
- GPR139 | c.641G>A p.S214N | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV58502783; called by muse, mutect2, varscan2
- GPR149 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67665860; called by muse, mutect2
- GPR18 | c.587del p.F196Sfs*2 | Frame Shift Del (DEL) | VAF 122/384 reads (32%) | catalogued as rs748201402; called by mutect2, varscan2
- GPR182 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV55626131; called by muse, mutect2, varscan2
- GPR45 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as COSV99307162; called by muse, mutect2
- GRB2 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as COSV57304468; called by muse, mutect2, varscan2
- GRIPAP1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1168735090, COSV64551946; called by muse, mutect2, varscan2
- GRK6 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62682576; called by muse, mutect2, varscan2
- GSTA5 | c.20T>A p.L7H | Missense Mutation (SNP) | VAF 171/483 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52862141; called by muse, mutect2, varscan2
- GTPBP1 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.133); catalogued as rs992562454, COSV53284579; called by muse, mutect2, varscan2
- H1-5 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161935569, COSV58899953; called by muse, mutect2, varscan2
- H2AC4 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV52518666; called by muse, mutect2, varscan2
- HAO2 | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 153/482 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV58039420; called by muse, mutect2, varscan2
- HARBI1 | c.749A>G p.N250S | Missense Mutation (SNP) | VAF 92/285 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58706046; called by muse, mutect2, varscan2
- HEATR6 | c.2372G>T p.S791I | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51745528; called by muse, mutect2, varscan2
- HECTD4 | c.4828C>T p.R1610W | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780528453, COSV66391597; called by muse, mutect2, varscan2
- HEPH | c.2004G>T p.Q668H (on ENST00000343002; = p.Q401H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/285 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.396); catalogued as COSV57963474; called by muse, varscan2
- HERC4 | c.2140C>T p.R714C (on ENST00000395198 / NM_022079.3; = p.R706C on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/480 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV53270872; called by muse, mutect2, varscan2
- HERPUD1 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.612); catalogued as COSV55862110; called by muse, mutect2, varscan2
- HEY2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs1184794935, COSV64239858; called by muse, mutect2, varscan2
- HK3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/76 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as rs779319370, COSV52839750; called by muse, mutect2, varscan2
- HNRNPCL1 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 94/356 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs377179680, COSV58609537; called by muse, mutect2, varscan2
- HOXC5 | c.583A>G p.N195D | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV54536846; called by muse, mutect2, varscan2
- HOXD3 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV50880048; called by muse, mutect2, varscan2
- HSPA2 | c.1564G>T p.V522L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.065); catalogued as COSV55969567; called by muse, mutect2, varscan2
- HSPG2 | c.3178C>T p.R1060W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs779360555, COSV65971365; called by muse, mutect2, varscan2
- HSPG2 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV65971368; called by muse, mutect2, varscan2
- HTT | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 110/326 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61861690; called by muse, mutect2, varscan2
- HVCN1 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 130/532 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs772902585, COSV54371866; called by muse, mutect2, varscan2
- IFT140 | c.3226_3228del p.E1076del | In Frame Del (DEL) | VAF 18/84 reads (21%) | catalogued as rs751137457; called by pindel, varscan2
- IGHG3 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1392911915; called by muse, mutect2, varscan2
- IGHV3-15 | c.105del p.S36Pfs*18 | Frame Shift Del (DEL) | VAF 63/215 reads (29%) | catalogued as rs781984574; called by mutect2, pindel, varscan2
- IGLV9-49 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 79/214 reads (37%) | catalogued as rs970074292; called by muse, mutect2, varscan2
- IGSF3 | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs1473378160, COSV100605054; called by muse, mutect2
- IL1R2 | c.696dup p.E233Rfs*27 | Frame Shift Ins (INS) | VAF 55/232 reads (24%) | catalogued as rs772911553; called by mutect2, varscan2
- ILDR1 | c.1387C>T p.R463C (on ENST00000344209 / NM_001199799.2; = p.R419C on NM_175924.4) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs778163752, CM110963, COSV56549053; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- ILK | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs776996356, COSV54990545; called by muse, mutect2, varscan2
- INO80E | c.42del p.K14Nfs*5 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs762875806; called by mutect2, varscan2
- INTS10 | c.304T>G p.L102V | Missense Mutation (SNP) | VAF 100/288 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs369004678; called by muse, mutect2, varscan2
- INTS8 | c.2419C>A p.Q807K | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV58250278; called by mutect2, varscan2
- IPO4 | c.2395G>A p.V799M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs747787561, COSV61016253; called by muse, mutect2, varscan2
- IQCN | c.2179G>A p.V727M | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs747225387, COSV66574249; called by muse, mutect2, varscan2
- IRF3 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55863104; called by muse, mutect2, varscan2
- IRX4 | c.718A>G p.K240E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs932256085, COSV51472406; called by muse, mutect2, varscan2
- ISLR2 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62301644; called by muse, mutect2, varscan2
- ITGA9 | c.978del p.M327Cfs*28 | Frame Shift Del (DEL) | VAF 62/228 reads (27%) | catalogued as COSV53235510, COSV99292303; called by mutect2, pindel, varscan2
- ITGB4 | c.3109C>T p.R1037W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1432276221, COSV52325581; called by muse, mutect2, varscan2
- ITSN1 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV66082918; called by muse, mutect2, varscan2
- IVNS1ABP | c.1431del p.G478Dfs*2 | Frame Shift Del (DEL) | VAF 154/640 reads (24%) | catalogued as COSV62252045; called by pindel, varscan2
- JAG1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs1286744339, COSV54756484; called by muse, mutect2, varscan2
- JAK1 | c.3141-1G>T p.X1047_splice | Splice Site (SNP) | VAF 42/134 reads (31%) | catalogued as COSV53807192; called by muse, mutect2, varscan2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 31/149 reads (21%) | catalogued as rs763250381; called by mutect2, pindel, varscan2
- KALRN | c.6620A>G p.Q2207R (on ENST00000360013 / NM_001024660.4; = p.Q510R on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as COSV99362821; called by muse, mutect2
- KCNH4 | c.642dup p.S215Vfs*39 | Frame Shift Ins (INS) | VAF 21/76 reads (28%) | catalogued as rs753954093; called by mutect2, varscan2
- KCNJ16 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 224/819 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs141270457; called by muse, mutect2, varscan2
- KCNK3 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57192451; called by muse, mutect2, varscan2
- KCNT1 | c.604C>T p.P202S (on ENST00000488444; = p.P221S on NM_020822.3) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53701090; called by muse, varscan2
- KHSRP | c.1093G>T p.G365W | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67919667; called by muse, mutect2, varscan2
- KIAA0513 | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs768254841, COSV50741283; called by muse, mutect2, varscan2
- KIAA0930 | c.462G>T p.E154D (on ENST00000336156 / NM_001009880.2; = p.E159D on NM_015264.2) | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.63); catalogued as COSV52663200; called by muse, mutect2, varscan2
- KIF18A | c.2491C>T p.R831W | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs142577501; called by muse, mutect2, varscan2
- KIF20B | c.2468G>A p.S823N (on ENST00000371728 / NM_001284259.2; = p.S783N on NM_016195.4) | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53306714; called by muse, mutect2, varscan2
- KIF26A | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as rs201102650, COSV59466497; called by muse, mutect2, varscan2
- KIFC1 | c.1681del p.L561Sfs*16 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as rs1562839389; called by mutect2, pindel, varscan2
- KIFC1 | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 135/449 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985318176, COSV65729191, COSV65729245; called by muse, mutect2, varscan2
- KIR3DL1 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 89/313 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as rs202067993, COSV58490536; called by muse, mutect2, varscan2
- KIRREL1 | c.1642C>T p.L548F | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.601); catalogued as COSV63287054; called by muse, mutect2, varscan2
- KLF16 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as rs1247847009, COSV51736568; called by muse, mutect2, varscan2
- KLHL17 | c.1185C>T p.G395= | Splice Region (SNP) | VAF 11/54 reads (20%) | catalogued as rs759811482, COSV58531919; called by muse, mutect2, varscan2
- KLHL31 | c.312del p.D105Tfs*15 | Frame Shift Del (DEL) | VAF 35/178 reads (20%) | catalogued as rs1227078726; called by mutect2, pindel, varscan2
- KMT2C | c.4273G>A p.G1425S | Missense Mutation (SNP) | VAF 72/225 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs746270757, COSV51436743; called by muse, mutect2, varscan2
- KPTN | c.273del p.K92Sfs*22 | Frame Shift Del (DEL) | VAF 27/127 reads (21%) | catalogued as COSV99645797; called by mutect2, pindel, varscan2
- L3MBTL4 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 94/363 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53121727; called by muse, mutect2, varscan2
- LAMA5 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs776963357, COSV53359402; called by muse, mutect2, varscan2
- LAMB3 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV61916754; called by muse, mutect2, varscan2
- LARP1 | c.1959G>A p.M653I (on ENST00000518297 / NM_033551.3; = p.M576I on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV60426914; called by muse, mutect2, varscan2
- LARP1B | c.2361del p.K787Nfs*26 | Frame Shift Del (DEL) | VAF 92/292 reads (32%) | catalogued as rs758463950; called by mutect2, varscan2
- LCAT | c.101dup p.H35Afs*7 | Frame Shift Ins (INS) | VAF 7/39 reads (18%) | catalogued as rs967875404; called by mutect2, pindel, varscan2
- LCTL | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs1392515852, COSV58422018; called by muse, mutect2, varscan2
- LILRA2 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52191341; called by muse, mutect2, varscan2
- LILRA5 | c.854A>G p.Q285R | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV56642666; called by muse, varscan2
- LILRB3 | c.337del p.L113Wfs*4 | Frame Shift Del (DEL) | VAF 52/228 reads (23%) | catalogued as rs1269949212; called by pindel, varscan2
- LIMK2 | c.1544del p.P515Lfs*4 | Frame Shift Del (DEL) | VAF 38/119 reads (32%) | catalogued as COSV59182050; called by mutect2, pindel, varscan2
- LIN54 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 163/533 reads (31%) | catalogued as COSV61200575; called by muse, mutect2, varscan2
- LINGO1 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62436954; called by muse, mutect2, varscan2
- LMNA | c.265C>A p.R89S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1515457, COSV61542879; called by muse, mutect2, varscan2
- LOXL2 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs756158305, COSV66691405; called by muse, mutect2
- LPIN3 | c.1098del p.G368Afs*52 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs1185012518; called by mutect2, varscan2
- LRCH1 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60847142; called by muse, mutect2, varscan2
- LRIG1 | c.943T>A p.S315T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.491); catalogued as COSV56239783; called by muse, mutect2, varscan2
- LRP2 | c.3617G>A p.R1206H | Missense Mutation (SNP) | VAF 123/352 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs377534549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC37A3 | c.2914A>G p.N972D | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs778092059, COSV59761353; called by muse, mutect2, varscan2
- LRRC43 | c.1680dup p.I561Hfs*37 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | catalogued as rs748039371; called by mutect2, varscan2
- LRRC4C | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53425009; called by muse, mutect2, varscan2
- LRRC55 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs773138988; called by muse, mutect2
- LRRC66 | c.474T>A p.N158K | Missense Mutation (SNP) | VAF 113/393 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58633605; called by muse, mutect2, varscan2
- LTBP4 | c.4103G>A p.R1368H (on ENST00000308370 / NM_001042544.1; = p.R1331H on NM_003573.2) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs759728325, COSV52581092; called by muse, varscan2
- MAP3K21 | c.811C>A p.L271I | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.557); catalogued as COSV64044562; called by muse, mutect2, varscan2
- MASP2 | c.159del p.G54Afs*26 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs1323205798; called by mutect2, pindel, varscan2
- MB21D2 | c.1371dup p.L458Tfs*7 | Frame Shift Ins (INS) | VAF 53/186 reads (28%) | catalogued as rs34835215; called by mutect2, varscan2
- MCCC2 | c.610A>G p.K204E | Missense Mutation (SNP) | VAF 79/442 reads (18%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.005); catalogued as COSV60154356; called by muse, mutect2, varscan2
- MDFI | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768704952, COSV57822002; called by muse, mutect2, varscan2
- MDGA2 | c.1454C>T p.T485I (on ENST00000399232 / NM_001113498.2; = p.T187I on NM_182830.4) | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62091735; called by muse, mutect2, varscan2
- MED26 | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.151); catalogued as rs771700366, COSV54660174; called by muse, mutect2, varscan2
- MEGF6 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as COSV53889526; called by muse, mutect2
- MEGF8 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.41); catalogued as rs1437893178, COSV99238267; called by muse, mutect2
- MEGF8 | c.5041G>A p.E1681K (on ENST00000251268 / NM_001271938.2; = p.E1614K on NM_001410.3) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); catalogued as rs767465945, COSV52083999; called by muse, mutect2, varscan2
- MESD | c.632dup p.K212Efs*19 | Frame Shift Ins (INS) | VAF 71/293 reads (24%) | catalogued as rs745891632; called by mutect2, varscan2
- MFSD1 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 127/449 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778213084, COSV51840560; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 125/387 reads (32%) | catalogued as rs780635289; called by mutect2, varscan2
- MGAT4B | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52977765; called by muse, varscan2
- MICAL3 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 228/714 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs531743473, COSV52896629; called by muse, mutect2, varscan2
- MINK1 | c.3412G>A p.V1138M | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1457793100, COSV53417908; called by muse, mutect2, varscan2
- MIPOL1 | c.656T>C p.M219T | Missense Mutation (SNP) | VAF 119/375 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV59383903; called by muse, mutect2, varscan2
- MISP | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779020440, COSV53120008; called by muse, mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 122/371 reads (33%) | catalogued as rs749903408; called by mutect2, varscan2
- MN1 | c.3099G>C p.K1033N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56558203; called by muse, mutect2
- MPLKIP | c.522del p.G175Efs*69 | Frame Shift Del (DEL) | VAF 170/612 reads (28%) | catalogued as rs1459084486; called by mutect2, pindel, varscan2
- MPO | c.872G>A p.C291Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56563652; called by muse, mutect2, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 56/206 reads (27%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MRPS18B | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs113079348, COSV52541319; called by muse, mutect2, varscan2
- MS4A10 | c.480C>A p.Y160* | Nonsense Mutation (SNP) | VAF 60/175 reads (34%) | catalogued as COSV57632558; called by muse, mutect2, varscan2
- MTMR4 | c.3110A>C p.E1037A | Missense Mutation (SNP) | VAF 101/335 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV60200533; called by muse, mutect2, varscan2
- MTNR1A | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as rs1414681123, COSV56155958; called by muse, mutect2, varscan2
- MUC16 | c.34211T>C p.V11404A | Missense Mutation (SNP) | VAF 253/730 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV67464143; called by muse, varscan2
- MUC5B | c.5681C>T p.T1894M | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs141754305, COSV71589925; called by muse, mutect2, varscan2
- MYBPC3 | c.1358del p.P453Lfs*13 | Frame Shift Del (DEL) | VAF 73/275 reads (27%) | catalogued as CD034631, CD1412241; called by mutect2, pindel, varscan2
- MYG1 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV52932916; called by muse, mutect2, varscan2
- MYH11 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750288554, COSV55552436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 54/138 reads (39%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO16 | c.2920A>G p.S974G | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as COSV51792440; called by muse, mutect2, varscan2
- MYO18B | c.7112C>A p.P2371H | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV59133731; called by muse, mutect2, varscan2
- MYO5A | c.3850-2A>G p.X1284_splice | Splice Site (SNP) | VAF 80/253 reads (32%) | catalogued as COSV62559995; called by muse, mutect2, varscan2
- MYOCD | c.2278T>C p.C760R | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV58503244; called by muse, mutect2, varscan2
- MZF1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as rs759875440; called by muse, mutect2
- NBEA | c.1567G>T p.V523F | Missense Mutation (SNP) | VAF 177/593 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59782033; called by muse, mutect2, varscan2
- NCAPH2 | c.267-2A>G p.X89_splice | Splice Site (SNP) | VAF 15/78 reads (19%) | catalogued as COSV55368728; called by muse, mutect2, varscan2
- NDRG1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV60483813; called by muse, mutect2, varscan2
- NDUFAB1 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 58/191 reads (30%) | catalogued as COSV50287266; called by muse, mutect2, varscan2
- NEBL | c.2981G>A p.G994D | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65802835; called by muse, mutect2, varscan2
- NEDD4 | c.2194G>A p.V732M (on ENST00000508342 / NM_001284338.1; = p.V313M on NM_006154.4) | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as rs550537760, COSV59061512; called by mutect2, varscan2
- NEDD4L | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 113/587 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs771098028, COSV56841218; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEK7 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 92/339 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs952495056, COSV66314943; called by muse, mutect2, varscan2
- NEPRO | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 129/414 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58723177; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NGEF | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV50921135, COSV50963847; called by muse, mutect2, varscan2
- NHLRC2 | c.2170T>C p.Y724H | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV65174831; called by muse, mutect2, varscan2
- NLRP12 | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.766); catalogued as rs1177743594, COSV60747108; called by muse, mutect2, varscan2
- NLRP14 | c.1759T>A p.Y587N | Missense Mutation (SNP) | VAF 99/352 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV55066896; called by muse, mutect2, varscan2
- NOL9 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 71/257 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.117); catalogued as rs745497641, COSV66625944; called by muse, mutect2, varscan2
- NOP56 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV61389879; called by muse, mutect2, varscan2
- NPC1L1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as rs145094484; called by muse, mutect2, varscan2
- NPHP1 | c.1322A>G p.Q441R (on ENST00000393272 / NM_207181.4; = p.Q442R on NM_000272.5) | Missense Mutation (SNP) | VAF 185/604 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57208464; called by muse, mutect2, varscan2
- NPY1R | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV56714396; called by muse, mutect2, varscan2
- NQO2 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 113/419 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV57642808; called by muse, mutect2, varscan2
- NR2F1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV59067504, COSV59068293; called by muse, mutect2, varscan2
- NR2F2 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.322); catalogued as rs774418448, COSV67683456; called by muse, mutect2, varscan2
- NRCAM | c.419G>A p.R140H (on ENST00000379028 / NM_001371124.1; = p.R134H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61036302; called by mutect2, varscan2
- NRXN2 | c.2777G>A p.S926N | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV55452734; called by muse, mutect2, varscan2
- NUAK2 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773889103, COSV65681370; called by muse, mutect2, varscan2
- NUP188 | c.4985T>A p.L1662H | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65330839; called by muse, mutect2, varscan2
- NUP62CL | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV65235873; called by muse, mutect2, varscan2
- NUTM1 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV60995343; called by muse, mutect2, varscan2
- NUTM1 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 93/258 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs202083206; called by muse, mutect2, varscan2
- NVL | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55872340; called by muse, varscan2
- NWD1 | c.1085T>G p.L362R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV60342064; called by muse, mutect2, varscan2
- NWD1 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs369799191; called by muse, mutect2, varscan2
- OBSCN | c.17299G>A p.V5767M | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769102934, COSV52771953; called by muse, mutect2, varscan2
- OCA2 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.087); catalogued as rs148468031, COSV62345033; called by muse, mutect2, varscan2
- ODF3 | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.549); catalogued as COSV57293725; called by muse, mutect2, varscan2
- OMD | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV65020186; called by muse, mutect2, varscan2
- OR10H2 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs774427304, COSV59945506; called by muse, mutect2, varscan2
- OR14K1 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.687); catalogued as COSV51721196; called by muse, mutect2, varscan2
- OR1D2 | c.46G>T p.G16W | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58921565; called by muse, mutect2, varscan2
- OR2B3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.744); catalogued as COSV65850915; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs755413956; called by mutect2, varscan2
- OR51T1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 120/420 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs781697460, COSV59025275; called by muse, varscan2
- OSBPL1A | c.1735C>T p.R579C (on ENST00000319481 / NM_080597.4; = p.R66C on NM_018030.4) | Missense Mutation (SNP) | VAF 110/352 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1339750569, COSV60198129; called by muse, mutect2, varscan2
- OSMR | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 81/253 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs371267287; called by muse, mutect2, varscan2
- OTUD7A | c.1216C>T p.H406Y (on ENST00000307050 / NM_001382637.1; = p.H399Y on NM_130901.3) | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61035771, COSV61038503; called by muse, mutect2, varscan2
- OXNAD1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 110/349 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs539458658, COSV53266648; called by muse, mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 64/194 reads (33%) | catalogued as rs763394045; called by mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 47/201 reads (23%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PARD3 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 113/406 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60749710, COSV60763903; called by muse, mutect2, varscan2
- PARP4 | c.4748A>G p.D1583G | Missense Mutation (SNP) | VAF 94/324 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV67961668; called by muse, mutect2, varscan2
- PASD1 | c.1762C>T p.Q588* | Nonsense Mutation (SNP) | VAF 101/313 reads (32%) | catalogued as COSV64855183; called by muse, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 54/192 reads (28%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PBRM1 | c.3100A>T p.K1034* (on ENST00000296302 / NM_001366071.2; = p.K1009* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 158/465 reads (34%) | catalogued as COSV56264862; called by muse, mutect2, varscan2
- PCDH10 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52093405; called by muse, mutect2, varscan2
- PCDH11X | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 123/380 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV53463485; called by muse, mutect2, varscan2
- PCDH15 | c.5183del p.G1728Afs*10 (on ENST00000644397 / NM_001354429.2; = p.G1670Afs*10 on NM_001142771.2) | Frame Shift Del (DEL) | VAF 109/359 reads (30%) | catalogued as COSV64685263; called by mutect2, pindel, varscan2
- PCDH17 | c.1357A>G p.N453D | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.9); catalogued as COSV64973829; called by muse, mutect2, varscan2
- PCDHA3 | c.698T>C p.L233S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs782383281, COSV65366869, COSV65371336; called by muse, mutect2, varscan2
- PCDHB16 | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV53361971; called by muse, mutect2, varscan2
- PCDHGA3 | c.1204T>C p.Y402H | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.33); catalogued as COSV99545927; called by muse, mutect2
- PCDHGA6 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV53894469; called by muse, mutect2, varscan2
- PCDHGA7 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV53943691; called by muse, mutect2, varscan2
- PCNP | c.259T>G p.S87A | Missense Mutation (SNP) | VAF 95/326 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV54576033; called by muse, mutect2, varscan2
- PCNT | c.3109G>A p.E1037K | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs119479063, CM080486; called by muse, varscan2
- PCSK9 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs367606156; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDK2 | c.874G>T p.G292C | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99143079; called by muse, mutect2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | catalogued as rs747131399; called by mutect2, varscan2
- PEX5 | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56954726; called by muse, mutect2, varscan2
- PGK2 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 117/337 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV59163747; called by muse, mutect2, varscan2
- PGS1 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767218343, COSV53145162; called by muse, mutect2, varscan2
- PHF11 | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 78/228 reads (34%) | catalogued as COSV62896475; called by muse, mutect2, varscan2
- PHF14 | c.2734G>T p.G912* | Nonsense Mutation (SNP) | VAF 110/316 reads (35%) | catalogued as rs373802740, COSV70997442; called by muse, mutect2, varscan2
- PHF20L1 | c.965dup p.N322Kfs*2 | Frame Shift Ins (INS) | VAF 38/208 reads (18%) | catalogued as rs755467695; called by mutect2, varscan2
- PHKB | c.1204+2T>C p.X402_splice | Splice Site (SNP) | VAF 82/261 reads (31%) | catalogued as rs1296112096, COSV54520695; called by muse, mutect2, varscan2
- PHOX2B | c.28A>G p.N10D | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56929463; called by muse, mutect2, varscan2
- PI4KA | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as COSV55410547; called by muse, mutect2, varscan2
- PIEZO2 | c.7397A>G p.Q2466R | Missense Mutation (SNP) | VAF 40/574 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99555416; called by muse, mutect2
- PIK3C2A | c.4853C>T p.T1618M | Missense Mutation (SNP) | VAF 294/970 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767495516, COSV56402611; called by mutect2, varscan2
- PIK3R2 | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55847864; called by muse, mutect2, varscan2
- PITRM1 | c.2265G>A p.M755I | Missense Mutation (SNP) | VAF 117/386 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs766365510, COSV56531052; called by muse, mutect2, varscan2
- PKNOX2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750281653, COSV53545465; called by muse, mutect2, varscan2
- PLB1 | c.4028_4030del p.F1343del | In Frame Del (DEL) | VAF 26/198 reads (13%) | catalogued as rs1383298835; called by pindel, varscan2
- PLBD2 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV55106685; called by muse, mutect2, varscan2
- PLCB4 | c.745-1G>A p.X249_splice | Splice Site (SNP) | VAF 50/176 reads (28%) | catalogued as rs746848167, COSV53801025; called by muse, mutect2, varscan2
- PLCH1 | c.435-1C>T p.X145_splice (on ENST00000340059 / NM_001130960.2; = p.X157_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 73/268 reads (27%) | catalogued as rs753615312, COSV58196346; called by muse, mutect2, varscan2
- PLRG1 | c.543del p.A182Pfs*47 | Frame Shift Del (DEL) | VAF 192/686 reads (28%) | catalogued as COSV57423801; called by mutect2, pindel, varscan2
- PLXND1 | c.1780A>G p.S594G | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as COSV60713009; called by muse, mutect2, varscan2
- PMM2 | c.229A>G p.K77E | Missense Mutation (SNP) | VAF 169/550 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV51631688; called by muse, mutect2, varscan2
- PMP2 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 211/878 reads (24%) | catalogued as COSV56267012, COSV99808089; called by muse, mutect2, varscan2
- PODXL2 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs759288912, COSV51741168; called by muse, mutect2, varscan2
- POLD1 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as rs547831370, COSV70955118, COSV70956565; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLD3 | c.898del p.R300Gfs*5 | Frame Shift Del (DEL) | VAF 26/95 reads (27%) | catalogued as rs761423306, COSV55240660; called by mutect2, varscan2
- POLE | c.2091dup p.F699Vfs*11 | Frame Shift Ins (INS) | VAF 28/76 reads (37%) | catalogued as rs752846614; ClinVar: uncertain significance; called by mutect2, varscan2
- POLE | c.1358A>G p.Q453R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV57679915; called by muse, mutect2, varscan2
- POLR3B | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 98/298 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV57278892; called by muse, mutect2, varscan2
- POPDC2 | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51740757; called by muse, mutect2, varscan2
- PPFIA1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.212); catalogued as COSV54134324; called by muse, mutect2, varscan2
- PPFIA2 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 256/751 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1201065713, COSV61031264; called by muse, varscan2
- PPM1D | c.539T>C p.I180T | Missense Mutation (SNP) | VAF 91/261 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV59955503; called by muse, mutect2, varscan2
- PPM1G | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 194/612 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV59769426; called by mutect2, varscan2
- PPP1R10 | c.2729C>A p.P910H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as COSV64739149; called by muse, mutect2, varscan2
- PPP1R15A | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52338920; called by muse, mutect2, varscan2
- PPP6R1 | c.1887G>T p.E629D | Missense Mutation (SNP) | VAF 81/251 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV69799704; called by muse, mutect2, varscan2
- PRAMEF20 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 166/642 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.082); catalogued as rs1298412469; called by muse, mutect2, varscan2
- PRB2 | c.431del p.P144Hfs*287 | Frame Shift Del (DEL) | VAF 89/409 reads (22%) | catalogued as rs771174009; called by mutect2, pindel, varscan2
- PRDM5 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.138); catalogued as rs1561361284, COSV53360053; called by muse, mutect2, varscan2
- PRKCSH | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770401000, COSV99371903; called by muse, mutect2
- PRPF4B | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as rs780716502, COSV61784093; called by muse, mutect2, varscan2
- PTEN | c.532_534del p.Y178del | In Frame Del (DEL) | VAF 88/390 reads (23%) | catalogued as rs587780711; called by pindel, varscan2
- PTGS1 | c.1165del p.L389Sfs*83 | Frame Shift Del (DEL) | VAF 72/173 reads (42%) | catalogued as rs778554144; called by mutect2, pindel, varscan2
- PTK7 | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV57848504; called by muse, mutect2, varscan2
- PTPRS | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV53618980; called by muse, mutect2, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs772722517, COSV99560265; called by pindel, varscan2
- PXDNL | c.1711G>T p.G571W | Missense Mutation (SNP) | VAF 99/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62486819; called by muse, mutect2, varscan2
- QRFPR | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV57676909; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 50/189 reads (26%) | catalogued as rs754588466; called by mutect2, varscan2
- RAB11FIP1 | c.2765A>G p.Q922R | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); catalogued as COSV54759957; called by muse, mutect2, varscan2
- RAB17 | c.232_234del p.E78del | In Frame Del (DEL) | VAF 30/108 reads (28%) | catalogued as rs1207339636; called by mutect2, pindel, varscan2
- RAB28 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV56539305; called by muse, mutect2, varscan2
- RAB40C | c.811dup p.Q271Pfs*7 | Frame Shift Ins (INS) | VAF 24/76 reads (32%) | catalogued as rs1555457247; called by mutect2, varscan2
- RABGGTA | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs759653199, COSV52863065; called by muse, mutect2, varscan2
- RAI2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV58964146; called by muse, mutect2, varscan2
- RANBP3 | c.130dup p.E44Gfs*3 | Frame Shift Ins (INS) | VAF 20/53 reads (38%) | catalogued as rs767283381; called by mutect2, pindel, varscan2
- RANBP9 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs1340505730, COSV50581189; called by muse, mutect2, varscan2
- RARG | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 93/292 reads (32%) | catalogued as COSV100553712, COSV58432875; called by muse, mutect2, varscan2
- RAVER1 | c.1097del p.P366Qfs*169 (on ENST00000615032; = p.P366Qfs*141 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs768618392, COSV53348646; called by mutect2, pindel, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 78/222 reads (35%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBCK1 | c.86A>G p.K29R | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV62292233; called by muse, mutect2, varscan2
- RBM26 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 17/607 reads (3%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.97); catalogued as rs913489380, COSV99936584; called by muse, mutect2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 36/123 reads (29%) | catalogued as rs749563266; called by mutect2, varscan2
- REC114 | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV58522161, COSV58522571; called by muse, mutect2, varscan2
- RECQL4 | c.2636del p.P879Lfs*69 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs1215700016; called by mutect2, pindel, varscan2
- RELN | c.7252A>G p.N2418D | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.467); catalogued as COSV59000574; called by muse, mutect2, varscan2
- REV1 | c.3385-1G>A p.X1129_splice | Splice Site (SNP) | VAF 84/297 reads (28%) | catalogued as COSV51484809; called by muse, mutect2, varscan2
- REV3L | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 161/472 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.243); catalogued as COSV62618715; called by muse, mutect2, varscan2
- RFX7 | c.2777C>T p.P926L (on ENST00000559447 / NM_001368074.1; = p.P1023L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100428385, COSV57963129; called by muse, mutect2, varscan2
- RGS12 | c.4244C>T p.A1415V (on ENST00000336727; = p.A767V on NM_198227.2) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV58751484; called by muse, mutect2, varscan2
- RIF1 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54616854; called by muse, varscan2
- RMND5B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV57744469; called by muse, mutect2, varscan2
- RNASEH2B | c.925del p.I309Lfs*26 | Frame Shift Del (DEL) | VAF 36/128 reads (28%) | catalogued as rs75254367; ClinVar: benign / likely benign; called by mutect2, varscan2
- RNF139 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.089); catalogued as COSV52679357; called by muse, mutect2, varscan2
- RNF207 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV65007652; called by muse, mutect2, varscan2
- RNF213 | c.6683A>T p.D2228V | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60396901; called by muse, mutect2, varscan2
- RNF213 | c.8389C>T p.R2797C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776731965, COSV60392376, COSV60396910; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RO60 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1197096039, COSV100814420, COSV66473753; called by muse, mutect2, varscan2
- ROBO1 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs778578401, COSV71394145; called by muse, mutect2, varscan2
- ROBO4 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs774678606, COSV100127234, COSV60623778; called by muse, mutect2, varscan2
- RPA3 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV56188316; called by muse, mutect2, varscan2
- RPL18 | c.264T>A p.D88E | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV50031724; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 76/226 reads (34%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPP38 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs752169129, COSV65382153; called by muse, mutect2, varscan2
- RPTN | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 434/1339 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs1167555229, COSV60167211; called by muse, varscan2
- RRP8 | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 160/588 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV54449516; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 100/154 reads (65%) | catalogued as rs759252078; called by mutect2, varscan2
- RUBCN | c.1831G>A p.V611I | Missense Mutation (SNP) | VAF 102/334 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs929802845, COSV56364365; called by muse, mutect2, varscan2
- RYR1 | c.7029C>T p.G2343= | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as rs138617219; called by muse, mutect2, varscan2
- RYR1 | c.9905del p.P3302Hfs*19 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs749656679; called by mutect2, varscan2
- SAMD4A | c.1246A>G p.K416E | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1239691279, COSV51880742; called by mutect2, varscan2
- SAMD9 | c.4393A>G p.K1465E | Missense Mutation (SNP) | VAF 89/312 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV66075020; called by muse, mutect2, varscan2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 41/138 reads (30%) | catalogued as rs771002611; called by pindel, varscan2
- SBF2 | c.5246C>T p.T1749I | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as rs1230579881, COSV56298510; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 257/870 reads (30%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCAF8 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 84/271 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367543808; called by muse, mutect2, varscan2
- SCAMP5 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as rs1331299833, COSV62643388; called by muse, mutect2, varscan2
- SCIMP | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 39/136 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as rs369470866; called by muse, mutect2, varscan2
- SCN1A | c.1927A>G p.S643G | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV57669276; called by muse, mutect2, varscan2
- SCN2A | c.5080A>G p.M1694V | Missense Mutation (SNP) | VAF 240/711 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as COSV51840359; called by muse, mutect2, varscan2
- SCN7A | c.4001C>T p.T1334I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV69271353; called by muse, mutect2, varscan2
- SCUBE1 | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 82/233 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749908505, COSV62611258, COSV62612465; called by muse, mutect2, varscan2
- SDR9C7 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs374904822; called by muse, mutect2, varscan2
- SEC14L2 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs763415556, COSV57241045, COSV57241899; called by muse, mutect2, varscan2
- SEC16B | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as rs1448896675, COSV57625412, COSV57625765; called by muse, varscan2
- SEC16B | c.842C>A p.P281H | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV57625421; called by muse, mutect2, varscan2
- SELENOP | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs778055332, COSV62792438, COSV62794425; called by muse, mutect2, varscan2
- SEMA3A | c.1370C>T p.T457I | Missense Mutation (SNP) | VAF 97/398 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1450292967, COSV54869878; called by muse, mutect2, varscan2
- SEMA3D | c.2267T>C p.M756T | Missense Mutation (SNP) | VAF 164/465 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV52392712; called by muse, mutect2, varscan2
- SENP5 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs777835943, COSV60207365; called by muse, mutect2, varscan2
- SFXN2 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV64012203; called by muse, mutect2, varscan2
- SGO2 | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs745955489, COSV63415329; called by muse, mutect2, varscan2
- SGSM3 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs563225500, COSV50652139; called by muse, mutect2, varscan2
- SH2B1 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV59462867; called by muse, mutect2, varscan2
- SH2B2 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs782021609, COSV60826278; called by muse, mutect2, varscan2
- SH3GL3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs149232982; called by muse, mutect2, varscan2
- SIK2 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 91/373 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.18); catalogued as rs773159979, COSV59252102; called by muse, mutect2, varscan2
- SIMC1 | c.914C>T p.P305L (on ENST00000443967 / NM_001308196.1; = p.P324L on NM_001308195.2) | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.003); catalogued as rs544006398, COSV57903170; called by muse, varscan2
- SIN3A | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 96/335 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237781040, COSV64582836; called by muse, mutect2, varscan2
- SKP2 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 117/363 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs756267784, COSV57041917; called by muse, mutect2, varscan2
- SLC10A7 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs201032148, COSV53880546; called by muse, mutect2, varscan2
- SLC13A1 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV52010952; called by muse, mutect2, varscan2
- SLC16A14 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 103/377 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs753933261, COSV54616677; called by muse, mutect2, varscan2
- SLC17A5 | c.846G>T p.W282C | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as COSV63287414; called by muse, mutect2, varscan2
- SLC20A1 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 158/526 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV55611253; called by muse, mutect2, varscan2
- SLC29A3 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV64385033; called by muse, mutect2, varscan2
- SLC2A2 | c.229A>C p.K77Q | Missense Mutation (SNP) | VAF 192/545 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV58585960; called by muse, mutect2, varscan2
- SLC4A1 | c.515del p.G172Vfs*2 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as COSV52263439; called by mutect2, pindel, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 25/77 reads (32%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC6A11 | c.1788G>A p.M596I | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV54393297; called by muse, mutect2, varscan2
- SLC9A6 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.273); catalogued as COSV65787946; called by muse, mutect2, varscan2
- SLC9C1 | c.2843G>A p.G948E | Missense Mutation (SNP) | VAF 131/406 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59888005; called by muse, mutect2, varscan2
- SLFN11 | c.1921A>G p.S641G | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV57698753; called by muse, mutect2, varscan2
- SLIT3 | c.1159A>G p.N387D | Missense Mutation (SNP) | VAF 69/245 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60607046; called by muse, mutect2, varscan2
- SLITRK2 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.391); catalogued as COSV59425245; called by muse, mutect2, varscan2
- SLK | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59825312; called by muse, mutect2, varscan2
- SMARCA4 | c.3005C>T p.A1002V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs1350288991, COSV60793892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMC1A | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV59129141; called by muse, mutect2, varscan2
- SMC1B | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV61581525; called by muse, mutect2, varscan2
- SMTN | c.1605del p.S536Vfs*33 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs758895137; called by mutect2, varscan2
- SNX25 | c.1231C>T p.Q411* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99253392; called by muse, mutect2
- SOCS4 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 36/132 reads (27%) | catalogued as rs765856971, COSV59460626; called by muse, mutect2, varscan2
- SOX14 | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60162603; called by muse, mutect2, varscan2
- SPATA31A3 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1447437015; called by muse, mutect2, varscan2
- SPATA5 | c.1448G>A p.G483D | Missense Mutation (SNP) | VAF 121/447 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV56775638; called by muse, mutect2, varscan2
- SPATA6 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 113/353 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs765166760, COSV64056583, COSV64057093; called by muse, mutect2, varscan2
- SPATA6 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 56/190 reads (29%) | catalogued as rs751433093, COSV64061003; called by mutect2, varscan2
- SPDL1 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142021941; called by muse, mutect2, varscan2
- SPICE1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs776057143; called by muse, mutect2
- SPIN1 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV65499277; called by muse, mutect2, varscan2
- SPSB2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs781906850, COSV51290168; called by muse, mutect2, varscan2
- SPTA1 | c.6071C>T p.S2024L | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs768854133, COSV63752715; called by muse, mutect2, varscan2
- SPTBN2 | c.1693G>T p.G565* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV59447249; called by muse, mutect2
- SPTY2D1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 125/500 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60473787; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs748467821; called by mutect2, varscan2
- SRCAP | c.7283G>A p.R2428H | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs763714146, COSV52672259; called by muse, mutect2, varscan2
- SREK1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 198/655 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs746498354, COSV52332818; called by muse, mutect2, varscan2
- SRPRA | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749114518, COSV59742262; called by muse, mutect2, varscan2
- ST6GAL2 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 56/194 reads (29%) | PolyPhen probably damaging (0.925); catalogued as COSV62416552; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as rs761646915, COSV52535489; called by muse, mutect2, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STARD3 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs754903815, COSV59223573; called by muse, mutect2, varscan2
- STARD8 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52925979; called by muse, mutect2, varscan2
- STAT1 | c.1276G>A p.V426I | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs143182587; called by muse, mutect2, varscan2
- STAT1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV63115349; called by muse, mutect2, varscan2
- STAT5A | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 97/316 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61806689; called by muse, mutect2, varscan2
- STK38 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 86/323 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as rs773297808, COSV57708838, COSV57709226; called by muse, mutect2, varscan2
- STON2 | c.1070C>T p.T357M (on ENST00000649389 / NM_001366849.2; = p.T300M on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs201611443; called by muse, mutect2, varscan2
- STPG1 | c.28C>T p.R10C (on ENST00000337248 / NM_001199013.2; = p.N2= on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 220/745 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.092); catalogued as rs377495393, COSV50219156; called by muse, mutect2, varscan2
- STX6 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as rs757942299, COSV51112057; called by muse, mutect2, varscan2
- STXBP2 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200306463, CM106813; called by muse, mutect2, varscan2
- SVEP1 | c.8605A>G p.R2869G | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as rs1430350033, COSV52839005; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 168/346 reads (49%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYDE2 | c.1283A>G p.H428R | Missense Mutation (SNP) | VAF 98/347 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1370427390, COSV52315416; called by muse, mutect2, varscan2
- SYF2 | c.216del p.A73Lfs*7 | Frame Shift Del (DEL) | VAF 195/587 reads (33%) | catalogued as rs1557470996; called by mutect2, varscan2
- SYNJ1 | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 95/287 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59147995; called by muse, mutect2, varscan2
- TAF1L | c.1823T>C p.I608T | Missense Mutation (SNP) | VAF 102/401 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54261613; called by muse, mutect2, varscan2
- TAF5 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 71/231 reads (31%) | catalogued as COSV60856921; called by muse, mutect2, varscan2
- TAF6 | c.1462del p.R488Gfs*4 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as COSV59842368; called by mutect2, pindel, varscan2
- TAF6L | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV53668426; called by muse, mutect2, varscan2
- TANC1 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55087646; called by muse, mutect2, varscan2
- TANGO6 | c.2743C>T p.P915S | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.224); catalogued as COSV55765010; called by muse, mutect2, varscan2
- TAOK1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 71/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55591409; called by muse, mutect2, varscan2
- TCAIM | c.1004T>C p.V335A | Missense Mutation (SNP) | VAF 106/366 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV61240865; called by muse, mutect2, varscan2
- TCTN1 | c.1283G>A p.R428Q (on ENST00000551590 / NM_001173975.3; = p.R414Q on NM_024549.6) | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369266915; called by muse, mutect2, varscan2
- TENM1 | c.7495C>T p.P2499S | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV64431294; called by muse, mutect2, varscan2
- TESK2 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 104/305 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as rs1038580098, COSV59151797; called by muse, mutect2, varscan2
- TF | c.562del p.Q188Sfs*27 | Frame Shift Del (DEL) | VAF 49/207 reads (24%) | catalogued as COSV53919394, COSV99395550; called by mutect2, pindel, varscan2
- TGFBR2 | c.229T>C p.C77R | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55449291, COSV99848090; called by muse, mutect2, varscan2
- TGM4 | c.1075G>T p.G359C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762160254, COSV99942596; called by muse, mutect2
- THBS2 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1276849599, COSV64678712; called by muse, mutect2, varscan2
- THOC2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV55545511; called by muse, mutect2
- THOC5 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 187/566 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs999138709, COSV63797612; called by muse, mutect2, varscan2
- THOC7 | c.21C>T p.D7= | Splice Region (SNP) | VAF 45/138 reads (33%) | catalogued as rs770808914; called by muse, mutect2, varscan2
- THRAP3 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV63567663; called by muse, mutect2, varscan2
- THRAP3 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs773025397, COSV57175656; called by muse, mutect2, varscan2
- TIGD3 | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.222); catalogued as COSV52889206; called by muse, varscan2
- TLR5 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV60558941; called by muse, mutect2, varscan2
- TM6SF1 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 136/453 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs367760723, COSV51946835; called by muse, mutect2, varscan2
- TMC4 | c.992G>A p.R331H (on ENST00000617472 / NM_001145303.3; = p.R325H on NM_144686.4) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV55827098; called by muse, mutect2, varscan2
- TMCO4 | c.1328A>G p.H443R | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs778190089, COSV53872455; called by muse, mutect2, varscan2
- TMEM131 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 103/341 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760959147, COSV51775610; called by muse, mutect2, varscan2
- TMEM190 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); catalogued as rs1327142602, COSV52581703; called by muse, varscan2
- TMEM192 | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 109/358 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs200586876, COSV60585130; called by muse, mutect2, varscan2
- TMEM198 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.769); catalogued as rs761312509, COSV99525507; called by muse, mutect2
- TMEM39A | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1004893648, COSV59900323; called by muse, mutect2, varscan2
- TMEM9 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs746735599, COSV66243827; called by muse, mutect2, varscan2
- TMEM95 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50135767; called by muse, varscan2
- TMPRSS11D | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52222360, COSV52223122; called by muse, mutect2, varscan2
- TMPRSS6 | c.2393A>G p.Q798R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV60977858; called by muse, mutect2, varscan2
- TMX1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1398861249, COSV63335528; called by muse, mutect2, varscan2
- TNFSF9 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs758057076, COSV55538325; called by muse, mutect2, varscan2
- TNRC18 | c.4627dup p.R1543Pfs*10 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs754233336; called by mutect2, varscan2
- TNRC6A | c.3435G>T p.E1145D | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV59364068; called by muse, mutect2, varscan2
- TNS3 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs770160923, COSV60790710; called by muse, mutect2, varscan2
- TNS4 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs777056955, COSV54184903; called by muse, mutect2, varscan2
- TPI1 | c.424G>A p.E142K (on ENST00000229270; = p.E105K on NM_000365.6) | Missense Mutation (SNP) | VAF 90/303 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51290166; called by muse, mutect2, varscan2
- TPP1 | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 105/390 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV54990547; called by muse, mutect2, varscan2
- TRAV38-1 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs1458576714; called by muse, mutect2, varscan2
- TRIM23 | c.1615C>A p.R539S | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51551240, COSV51552623; called by muse, mutect2, varscan2
- TRIM3 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV61983830; called by muse, mutect2, varscan2
- TRIM75P | c.1271T>C p.I424T | Missense Mutation (SNP) | VAF 107/345 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV72295838; called by muse, mutect2, varscan2
- TRIOBP | c.6040del p.L2014* (on ENST00000644935 / NM_001039141.3; = p.L301* on NM_007032.5) | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs1569058232; called by mutect2, pindel, varscan2
- TRIT1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 101/376 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.108); catalogued as rs149680997; called by muse, mutect2, varscan2
- TRIT1 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 156/472 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.232); catalogued as rs761935152, COSV57548140; called by muse, mutect2, varscan2
- TRPV2 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58428176; called by muse, mutect2, varscan2
- TRPV4 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368937671; called by muse, mutect2, varscan2
- TRRAP | c.7154A>G p.Q2385R (on ENST00000359863 / NM_001244580.1; = p.Q2367R on NM_003496.3) | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV62843951; called by muse, mutect2, varscan2
- TSPAN32 | c.475_476del p.K159Vfs*12 | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | catalogued as COSV51719829; called by mutect2, pindel, varscan2
- TSPO2 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs750976131, COSV55109169; called by muse, mutect2, varscan2
- TSPYL5 | c.907T>C p.Y303H | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59071614; called by muse, mutect2, varscan2
- TSR1 | c.174C>G p.S58R | Missense Mutation (SNP) | VAF 90/294 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.065); catalogued as COSV52157781; called by muse, mutect2, varscan2
- TSSK6 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV53063571; called by muse, mutect2, varscan2
- TTC3 | c.3769G>A p.V1257I | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV61289946; called by muse, mutect2, varscan2
- TTC37 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 114/540 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436774058, COSV62454688; called by muse, mutect2, varscan2
- TTLL5 | c.1110_1111del p.P371Ffs*5 | Frame Shift Del (DEL) | VAF 175/716 reads (24%) | catalogued as rs1566831299; called by pindel, varscan2
- TTN | c.97789C>T p.R32597C (on ENST00000591111; = p.R25173C on NM_003319.4) | Missense Mutation (SNP) | VAF 79/286 reads (28%) | PolyPhen benign (0.003); catalogued as rs1423837818, COSV60041827; called by muse, mutect2, varscan2
- TTN | c.77959G>T p.G25987* (on ENST00000591111; = p.G18563* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 56/167 reads (34%) | catalogued as COSV100616087, COSV60041903; called by muse, mutect2, varscan2
- TTN | c.64291A>T p.I21431F (on ENST00000591111; = p.I14007F on NM_003319.4) | Missense Mutation (SNP) | VAF 50/197 reads (25%) | PolyPhen possibly damaging (0.787); catalogued as COSV60041941; called by muse, mutect2, varscan2
- TTN | c.10917del p.F3640Lfs*79 (on ENST00000591111; = p.F3594Lfs*79 on NM_003319.4) | Frame Shift Del (DEL) | VAF 40/140 reads (29%) | catalogued as COSV100601941, COSV100621738, COSV60041999; called by mutect2, pindel, varscan2
- TTYH1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV56611635; called by muse, mutect2, varscan2
- TUBB2A | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV61318978; called by muse, mutect2, varscan2
- TULP3 | c.358T>A p.S120T | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV68117787; called by muse, mutect2, varscan2
- UBE4B | c.1329del p.A444Hfs*14 (on ENST00000343090 / NM_001105562.3; = p.A315Hfs*14 on NM_006048.5) | Frame Shift Del (DEL) | VAF 49/140 reads (35%) | catalogued as rs758215455, COSV53529804; called by mutect2, varscan2
- UBQLN2 | c.1574dup p.G526Wfs*19 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | catalogued as rs757430527; called by mutect2, varscan2
- UMOD | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs141355380, COSV100207845; called by muse, mutect2, varscan2
- UNC5B | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759839363, COSV58977021; called by muse, mutect2, varscan2
- UPF3A | c.1007+1G>A p.X336_splice | Splice Site (SNP) | VAF 48/146 reads (33%) | catalogued as rs913816164, COSV60894971; called by muse, mutect2, varscan2
- UPK2 | c.150del p.C51Vfs*10 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | catalogued as rs750952264; called by mutect2, pindel, varscan2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 53/196 reads (27%) | catalogued as rs754361807; called by mutect2, varscan2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
483 further variants in this file (213 protein-altering or splice-affecting, 248 silent, 22 other) are not listed here.
